TCGA case TCGA-05-4424 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/66763a0c-6cda-4832-a0cc-e7b496d78eaa

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.3 years (25,689 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 30 days; Days to treatment end: 30 days; Treatment dose: 60 Gy; Treatment outcome: Partial Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 153 days; Treatment dose: 3 Gy; Treatment outcome: Treatment Ongoing; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Erlotinib; Days to treatment start: 699 days (1.9 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 699 days (1.9 years); Treatment dose: 30 Gy; Treatment outcome: Treatment Ongoing; Treatment anatomic sites: Distant Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma with mixed subtypes). Age at diagnosis: 70.8 years (25,842 days); Days to diagnosis: 153 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (2 entries)
- Day 153 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 153 days.
- Days to follow up: 913 days (2.5 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 50; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 2007.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-05-4424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-05-4424-01A-01-BS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-05-4424-01A-02-BS2: Section location: Bottom; Percent tumor cells: 67; Percent tumor nuclei: 75; Percent normal cells: 25; Percent necrosis: 3; Percent stromal cells: 5.
- Sample TCGA-05-4424-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-05-4424-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; Treatment outcome at TCGA followup: Partial Remission/Response.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 913 days; disease-specific survival: no event (censored), 913 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 153 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-05-4424-01A-22D-1854-01): tumor purity 0.24, ploidy 4.42, whole-genome doublings 2.
